Surgical pathology report (de-identified scan), TCGA case TCGA-29-1776, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1776-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1776

Surg Path

CLINICAL HISTORY:

Abdominal pelvic swelling NOS.

GROSS EXAMINATION:

A. "Omentum", Received is an omental specimen (16 x 11 x 4.5 cm) that is thick and rubbery (AF1 Frozen section; remnant in A1, additional blocks A2).

B. "Right tube and ovary". Received is a 5.5 x 5 x 4.2 cm solid and cystic white-red ovarian cancer mass (40 gm) with multiple serosal excrescences maximally 4.2 x 2.5 x 0.4 cm. Cut section reveals that the white-yellow tumor is 20% cystic; the rest is filled with a light tan serous fluid. There is no residual normal ovary. The fallopian tube has a patent lumen but no fimbria.

BLOCK SUMMARY:

B1- tumor along with external excrescence

B2- cyst wall and adherent tumor

B3- tentative fallopian tube

C. "Left tube and ovary". Received is 19.6 gm 5.2 x 3 x 2.8 cm white-tan mass with two cysts measuring 1 x 0.9 x 0.6 cm for the first and 0.8 x 0.6 x 0.4 cm for the second. The outer surface is significant for white fibrous adherent fragment which can be peeled off and grossly resembles the tumor in the other ovary. Sectioning reveals a white-tan cut surface with multiple corpora albicans and three cysts cavity. The cysts cavity contains a thin serous solution which is red clear. The largest of the cysts which is 2 x 1.5 x 0.8 cm is on the most proximal portion of the ovary. The fallopian tube (1 cm in length x 0.8 cm in diameter is red-tan and upon sectioning has a patent lumen.

BLOCK SUMMARY:

C1 Ovarian tumor with cyst

C2- cyst wall and adherent tumor

C3- fallopian tube

D. "Uterus", received is a 263 gm, 10.5 x 9 x 6.8 cm uterus without a cervix. Bivalving the uterus reveals a 7.1 x 3.5 cm uterine cavity with multiple subserosal leiomyomata. These leiomyomata on serial sectioning reveal an endometrium averages of 0.1 cm with a myometrium measuring 3.1 cm there are two large (3 x 2.5 x 2.5 cm) white whorled fibrous lesion which expand when on the cut surface. The endometrium is moderately hemorrhagic. The serosal surface of the uterus demonstrate a shiny purple surface with multiple adherent small fibrous tissue which grossly resemble the ovarian tumor.

BLOCK SUMMARY:

D1-D2 anterior endomyometrium bisected

D3- leiomyomata

D4-D5 posterior endomyometrium bisected with leiomyomata

D6- adherent tumor to serosa of uterus

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- metastatic adenocarcinoma
consistent with ovarian primary

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

[page 2 of 2]
TCGA-29-1776

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY & OOPHORECTOMY

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

B. RIGHT OVARY:

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 5.5 X 5 X 4.2 CM

WEIGHT: 40 GM

Serosa: INVOLVED

WITH METASTATIC/IMPLANTED TUMOR, INVOLVING THE FOLLOWING SPECIMENS

A. OMENTUM

C. LEFT OVARY: EXTENSIVE ENDOMETRIOID ADENOCARCINOMA.

D. UTERUS, 263 GRAMS

Serosa: EXTENSIVE TUMOR

Endometrium: ATROPHIC

Myometrium: ADENOMYOSIS

Cervix: NOT SUBMITTED

THE FOLLOWING SPECIMENS ARE FREE OF TUMOR

B. RIGHT FALLOPIAN TUBE: NO PATHOLOGIC DIAGNOSIS.

C. LEFT FALLOPIAN TUBE: NO PATHOLOGIC DIAGNOSIS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Performed by: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b4c0ff89-9b40-456e-9ae1-8279cf55a52d (TCGA-29-1776.EB6DF66E-C6EE-4C63-889D-9F4B6CA170C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).